Gene-level copy-number profile of tumor specimen C3N-02758-01 (profiled together with C3N-02758-02) from CPTAC case C3N-02758, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 76.7 years (28,030 days).
Specimen C3N-02758-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5d63328a-4baf-4651-be27-4733bd5f1a2f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02758-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/67ac660a-710f-4f18-a255-e2aa23dbb795

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 15; copy number 2: 2,579; copy number 3: 175; copy number 4: 25,359; copy number 5: 2,234; copy number 6: 21,943; copy number 7: 939; copy number 8: 4,241; copy number 9: 77; copy number 10: 103; copy number 11: 55; copy number 12: 99; copy number 13: 105; copy number 14: 134; copy number 15: 5; copy number 16: 7; copy number 17: 23; copy number 18: 39; copy number 19: 90; copy number 20: 18; copy number 21: 14; copy number 23: 42; copy number 24: 9; copy number 25: 2; copy number 26: 4; copy number 27: 38; copy number 30: 3; copy number 31: 14; copy number 33: 7; copy number 43: 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–4): AL359922.1.
- chr9:21,929,457–23,438,700, 15 genes (within-gene range 0–4): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:60,914,407–60,964,196, 5 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr21:13,038,160–13,067,033, 2 genes: ANKRD30BP2, RNU6-614P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 542 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,030,534–38,063,791, 2 genes, copy number 11: EIF4EBP1, AP006545.1.
- chr8:38,105,493–38,150,992, 4 genes, copy number 9 (within-gene range 2–9): ASH2L, RNU6-988P, AC084024.1, STAR.
- chr8:41,653,220–41,896,762, 1 gene, copy number 9 (within-gene range 4–9): ANK1.
- chr8:41,803,349–42,737,407, 24 genes, copy number 9: Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2.
- chr8:73,688,691–75,566,834, 37 genes, copy number 10–23 (within-gene range 4–23): AC022826.2, UBE2W, AC022826.1, RN7SL760P, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G.
- chr8:76,403,998–76,683,308, 5 genes, copy number 12–15 (within-gene range 4–15): AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1.
- chr8:76,966,768–77,014,028, 3 genes, copy number 10: MIR3149, PEX2, HIGD1AP18.
- chr8:78,268,637–78,558,503, 1 gene, copy number 18 (within-gene range 3–18): PKIA-AS1.
- chr8:78,516,340–78,956,082, 8 genes, copy number 11–18: PKIA, AC068700.1, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605.
- chr8:79,520,145–83,408,900, 77 genes, copy number 10–19 (broad region; genes not listed).
- chr8:85,744,543–86,743,675, 26 genes, copy number 9 (within-gene range 2–9): REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10.
- chr8:96,645,242–101,669,726, 110 genes, copy number 11–31 (broad region; genes not listed).
- chr8:105,826,570–107,648,032, 14 genes, copy number 26–43: AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, HMGB1P46, ANGPT1, PGAM1P13.
- chr8:115,408,496–116,403,757, 6 genes, copy number 9–30: TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1.
- chr8:121,639,293–123,541,206, 40 genes, copy number 14–18 (within-gene range 4–18): HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32.
- chr8:123,851,987–124,120,061, 1 gene, copy number 33 (within-gene range 2–33): FER1L6.
- chr8:123,984,138–128,564,679, 77 genes, copy number 19–33 (broad region; genes not listed).
- chr8:129,241,228–129,291,275, 3 genes, copy number 21: AC103833.2, AC103833.1, RN7SKP206.
- chr8:130,595,299–131,317,632, 6 genes, copy number 9: AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1.
- chr8:131,712,512–132,481,095, 6 genes, copy number 10: AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3.
- chr8:133,237,175–133,644,725, 9 genes, copy number 14: NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1.
- chr8:134,783,694–134,804,945, 4 genes, copy number 11: AC083843.3, AC083843.2, MIR30B, MIR30D.
- chr8:134,838,069–135,299,719, 4 genes, copy number 9–12: NCRNA00250, AC103764.1, RPL23AP56, LINC01591.
- chr17:22,567,423–22,568,713, 1 gene, copy number 10: AC131055.2.
- chr21:30,165,565–30,166,805, 1 gene, copy number 11: CLDN17.
- chr21:36,698,773–39,929,397, 72 genes, copy number 13–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
